Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAY1, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAY1-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

MRN:

DOB: (Age:)

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: Innominate vein
2. Thymus: Thymoma

ICD C-3
Thymoma, type AB
malignant 8582/3
Site: Thymus C37.9
JAN 5/21/14

DIAGNOSIS

1. Lymph node, biopsy (innominate vein lymph node):
-Lymph node, negative for malignancy
2. Thymus, resection:
- a) Thymoma, WHO type AB2 (mixed thymoma), with:
- i) Greatest tumor dimension = 7.0 cm
- ii) Focal microscopic invasion of tumor capsule
- b) Thymic tissue with involutional changes

SYNOPTIC DATA

Specimen Type:	Not specified
Specimen Size:	Greatest dimension: 12.5 cm
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 7.0 cm
Histologic Type:	Type AB thymoma (mixed)
Pathologic Staging:	Stage IIa: Microscopic transcapsular invasion
Regional Lymph Nodes: metastasis	pN0: No regional lymph node
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor

COMMENT

Sections examined show an encapsulated tumor composed of alternating

[page 2 of 3]
Patient Name:.

MRN:

DOB: (Age:)

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

areas of bland spindled cells without significant lymphocytic infiltration, and areas of polygonal epithelioid cells admixed with small round lymphocytes. There is focal microscopic invasion of the capsule with extension into adjacent mediastinal fat. By immunohistochemistry, the epithelial cells are positive for keratins (CK5/6, AE1/AE3) and p63. The infiltrating lymphocytes stain positive for CD5. CD20 shows focal positive staining of lymphocytes and occasional epithelial cells. CD1a is non-reactive. The overall morphological and immunohistochemical profile of this lesion is consistent with a mixed thymoma (WHO type AB2), modified Masaoka stage IIa.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Mediastinal tumour

GROSS DESCRIPTION

1. The specimen container is labeled with the patient's name and as "innominate vein lymph node" contains one lymph node received in 10% buffered formalin. The lymph node measures 0.5 x 0.5 x 2.3 cm. 1A specimen submitted in toto.

2. The specimen container is labeled with the patient's name and as "thymoma" contains a thymus gland received in 10% buffered formalin. The thymus measures 12.5 x 6.1 x 3.0 cm and weighs 71 g. The specimen margins are painted with silver nitrate. On sectioning, there is presence of a well-circumscribed tumor measuring 7.0 x 5.0 x 3.5 cm. The tumor appears to be grossly encapsulated; the capsule is mobile on the surface of the tumor. The cut surface of the tumor is whitish tan in color and appears to be firm and solid. The rest of the thymus tissue is yellowish tan in color and is predominantly fatty. No other nodules are identified grossly.

Representative sections are submitted as follows:

2A-2G representative sections of the tumor including capsule and adjacent apparently normal thymus tissue.

2H-2I representative sections of the apparently normal thymus.

[page 3 of 3]
Patient Name

MRN:

DOB: (Age:)

Gender: F

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Page: 3 of 3

Source: NCI Genomic Data Commons file b691992e-c883-40c9-8401-0b8e1ff00710 (TCGA-XU-AAY1.127934A1-BE6A-4661-A570-45934AB914EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).